Somatic mutation profile of tumor specimen C3N-04284-01 (aliquot CPT0247090006) from CPTAC case C3N-04284, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 80.3 years (29,323 days).
Specimen C3N-04284-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1066f5fb-23e8-4679-913f-10fd1636c2f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04284-31 (Blood Derived Normal), aliquot CPT0247130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db6f5bdd-73e8-4079-a15d-c08682f95174

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 4, Silent 4, 3'Flank 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKHD1 | c.5323C>T p.R1775* | Nonsense Mutation (SNP) | VAF 44/888 reads (5%) | catalogued as rs770522674, CM051152, COSV61874720; ClinVar: pathogenic; called by muse, mutect2
- ACTG2 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.072); catalogued as rs1208008180, COSV61827771; called by muse, mutect2
- AZU1 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1423981588; called by muse, mutect2
- KIF26B | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.103); catalogued as rs776974187, COSV101313961; called by muse, mutect2
- SLC39A4 | c.869C>T p.P290L (on ENST00000301305 / NM_001374839.1; = p.P265L on NM_017767.3) | Missense Mutation (SNP) | VAF 27/568 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs142764754; ClinVar: uncertain significance; called by muse, mutect2
- TRIO | c.7264G>A p.A2422T | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.014); catalogued as rs1469803121; called by muse, mutect2, varscan2
- ANKRD63 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIPR1 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2
- LFNG | c.424A>G p.K142E | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by muse, mutect2
- MUC16 | c.3857T>C p.I1286T | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2
- NIN | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NPAS1 | c.753G>T p.M251I | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2
- POGLUT1 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC17A1 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- SPIN2B | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 21/734 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2
- SPTBN5 | c.8104A>G p.N2702D | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZMYM4 | c.632A>T p.H211L | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2
- BHLHE41 | c.855C>A p.R285= | Silent (SNP) | VAF 22/192 reads (11%) | called by muse, mutect2
- C5orf38 | c.30C>T p.L10= | Silent (SNP) | VAF 24/430 reads (6%) | called by muse, mutect2
- CENPF | c.7350C>A p.L2450= | Silent (SNP) | VAF 24/350 reads (7%) | called by muse, mutect2
- LDOC1 | c.162C>T p.P54= | Silent (SNP) | VAF 51/516 reads (10%) | catalogued as COSV100983186; called by muse, mutect2
- CYP21A1P | chr6:32008626 C>T | 3'Flank (SNP) | VAF 70/730 reads (10%) | catalogued as rs990264066; called by muse, mutect2
- DNAH14 | c.9205+9195C>T | Intron (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- MCF2 | c.-3G>A | 5'UTR (SNP) | VAF 30/724 reads (4%) | catalogued as rs769742766, COSV100645046; called by muse, mutect2
- SYTL1 | c.747+85G>A | Intron (SNP) | VAF 16/400 reads (4%) | called by muse, mutect2
- TEPSIN | c.1029+31G>A | Intron (SNP) | VAF 15/286 reads (5%) | catalogued as rs886925844, COSV100329616; called by muse, mutect2
- ZNF552 | c.33+90C>G | Intron (SNP) | VAF 33/292 reads (11%) | catalogued as rs1413073497; called by muse, mutect2, varscan2
